CCDI case PBCNFI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/de34d3e4-f680-4a33-9403-e77074cd581a

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Epithelial tumor, benign: ICD-O-3 morphology code: 8010/0; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 14.8 years (5,394 days).

Biospecimens (3 samples)
- Sample 0DVR5Z: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVR73: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVR7X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
